Somatic mutation profile of tumor specimen C3N-01220-03 (aliquot CPT0076340012) from CPTAC case C3N-01220, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 51.3 years (18,748 days).
Specimen C3N-01220-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50c66882-8634-4153-b143-c3d65ee6dc2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01220-71 (Blood Derived Normal), aliquot CPT0076400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb575490-80f9-4c3c-9451-80156ad7ad32

The open-access MAF lists 101 somatic variants for this specimen: 60 protein-altering or splice-affecting, 28 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 28, Intron 7, Splice Site 5, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, 5'UTR 1, 3'UTR 1, Translation Start Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4715+1G>T p.X1572_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, mutect2, varscan2
- AFF4 | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs751474496; called by muse, mutect2
- ANK2 | c.11333G>A p.G3778E | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); catalogued as COSV52147199, COSV52178677; called by muse, mutect2, varscan2
- ANKRD34B | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 21/173 reads (12%) | catalogued as COSV58613404; called by muse, mutect2, varscan2
- ANO2 | c.2363C>T p.P788L (on ENST00000356134 / NM_001278597.3; = p.P792L on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370114605; called by muse, mutect2, varscan2
- ARHGAP23 | c.2439C>G p.D813E | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs1049336617; called by muse, mutect2, varscan2
- BTBD10 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1381566101; called by muse, mutect2, varscan2
- CLCN1 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1473430259, COSV58368059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYM | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs553362900, COSV99561970; called by muse, mutect2, varscan2
- DOCK1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV54728364; called by muse, mutect2, varscan2
- EFR3A | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 24/154 reads (16%) | catalogued as rs764347591, COSV99602292; called by muse, mutect2, varscan2
- FGD5 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV53240622; called by muse, mutect2, varscan2
- FNIP1 | c.2338C>T p.H780Y | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.253); catalogued as rs756786251; called by muse, mutect2, varscan2
- HMMR | c.508T>A p.L170M | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100700997; called by muse, mutect2, varscan2
- IQGAP3 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63254652; called by muse, mutect2, varscan2
- KANSL3 | c.2210C>G p.P737R (on ENST00000666923 / NM_001349262.2; = p.P711R on NM_001115016.3) | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs954265164; called by muse, mutect2, varscan2
- KCTD15 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as rs757471584, COSV52289992; called by muse, mutect2, varscan2
- KLHL33 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1363315688; called by muse, mutect2, varscan2
- MYH3 | c.645G>C p.G215= | Splice Region (SNP) | VAF 62/401 reads (15%) | catalogued as COSV56862257; called by muse, mutect2, varscan2
- PCBP1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs368303566; called by muse, mutect2, varscan2
- QARS1 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs62621222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TJP2 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142684074, COSV55271491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGGT1 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs1181179801; called by muse, mutect2, varscan2
- UNC13D | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 120/814 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99256156; called by muse, mutect2, varscan2
- ZNF638 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 71/363 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV52485440; called by muse, mutect2, varscan2
- ACAD9 | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ARHGAP12 | c.2139G>T p.L713F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ARHGEF33 | c.1221+1del | Frame Shift Del (DEL) | VAF 37/179 reads (21%) | called by mutect2, pindel, varscan2
- CORIN | c.1736-12_1738del p.X579_splice | Splice Site (DEL) | VAF 51/169 reads (30%) | called by mutect2, pindel
- CYP46A1 | c.970A>T p.I324F | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- DNHD1 | c.2520T>A p.N840K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- DOC2A | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 108/527 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK1 | c.549T>A p.S183R | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DYNC1H1 | c.7556G>A p.R2519K | Missense Mutation (SNP) | VAF 32/474 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2
- ELOVL7 | c.256-1G>C p.X86_splice | Splice Site (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
- EPS8 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- HAS3 | c.442T>G p.F148V | Missense Mutation (SNP) | VAF 110/520 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HELQ | c.3238G>T p.V1080L | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- IRF4 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KCNG1 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTCAP3 | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LRP6 | c.3294del p.F1098Lfs*4 | Frame Shift Del (DEL) | VAF 37/215 reads (17%) | called by mutect2, pindel, varscan2
- MICU3 | c.1503C>A p.D501E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- MUC4 | c.8627G>T p.G2876V | Missense Mutation (SNP) | VAF 54/961 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH13 | c.2283G>T p.R761S | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- NUDT6 | c.-3_14delinsCG | Translation Start Site (DEL) | VAF 24/146 reads (16%) | called by pindel, varscan2*
- PIK3R1 | c.1715_1718delinsC p.Q572_L573delinsP (on ENST00000521381 / NM_181523.3; = p.Q302_L303delinsP on NM_181504.4) | In Frame Del (DEL) | VAF 32/128 reads (25%) | called by pindel, varscan2*
- PIK3R4 | c.1718C>G p.A573G | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- RECK | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RPS6KB1 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SFMBT2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SLC44A1 | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SOBP | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 102/433 reads (24%) | called by muse, mutect2, varscan2
- SPATA5 | c.1999T>A p.Y667N | Missense Mutation (SNP) | VAF 98/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPIN3 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPPL2A | c.361-1G>T p.X121_splice | Splice Site (SNP) | VAF 14/82 reads (17%) | called by mutect2, varscan2
- TAZ | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TWF1 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- VN1R1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 84/315 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- YEATS2 | c.3754G>A p.D1252N | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- AL592490.1 | c.60G>A p.A20= | Silent (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- CDC25B | c.1134C>T p.H378= (on ENST00000245960 / NM_021873.3; = p.H364= on NM_004358.4) | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as rs560679507, COSV99848466; called by muse, varscan2
- COL11A1 | c.1512C>A p.S504= | Silent (SNP) | VAF 112/396 reads (28%) | called by muse, mutect2, varscan2
- CSMD2 | c.5190C>A p.T1730= | Silent (SNP) | VAF 48/273 reads (18%) | called by muse, mutect2, varscan2
- DDX11 | c.1737C>T p.D579= | Silent (SNP) | VAF 95/388 reads (24%) | catalogued as rs755996490; called by muse, mutect2, varscan2
- EPYC | c.249A>G p.E83= | Silent (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- FAM72A | c.234G>T p.G78= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as COSV100367265; called by muse, mutect2, varscan2
- FBXW12 | c.1392G>A p.T464= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs749755227, COSV56483295; called by muse, mutect2, varscan2
- FNDC11 | c.549C>T p.H183= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs1352060707; called by muse, mutect2, varscan2
- KCNG1 | c.1336C>T p.L446= | Silent (SNP) | VAF 32/160 reads (20%) | called by muse, mutect2, varscan2
- KIAA0930 | c.324C>G p.L108= (on ENST00000336156 / NM_001009880.2; = p.L113= on NM_015264.2) | Silent (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- KIF3C | c.1203G>T p.G401= | Silent (SNP) | VAF 41/204 reads (20%) | called by muse, mutect2, varscan2
- LILRB2 | c.24G>C p.L8= | Silent (SNP) | VAF 25/216 reads (12%) | called by muse, mutect2, varscan2
- LRP2 | c.9798C>T p.N3266= | Silent (SNP) | VAF 57/196 reads (29%) | catalogued as rs1481482183; called by muse, mutect2, varscan2
- MAPK8IP2 | c.711C>T p.S237= | Silent (SNP) | VAF 38/179 reads (21%) | catalogued as rs1429065925; called by muse, mutect2, varscan2
- MYOT | c.207C>T p.F69= | Silent (SNP) | VAF 38/232 reads (16%) | called by muse, mutect2, varscan2
- NIN | c.3297G>A p.E1099= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- PAPSS2 | c.789C>T p.G263= | Silent (SNP) | VAF 120/494 reads (24%) | called by muse, mutect2, varscan2
- PCDH15 | c.5124A>G p.P1708= | Silent (SNP) | VAF 81/395 reads (21%) | called by muse, mutect2, varscan2
- PLEC | c.10155C>T p.G3385= (on ENST00000322810 / NM_201380.4; = p.G3275= on NM_000445.5) | Silent (SNP) | VAF 107/557 reads (19%) | called by muse, mutect2, varscan2
- SFTPD | c.183C>T p.G61= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as rs148973610; called by muse, mutect2, varscan2
- SLC7A3 | c.120G>T p.L40= | Silent (SNP) | VAF 49/158 reads (31%) | catalogued as COSV99979501; called by muse, mutect2, varscan2
- SMTNL2 | c.291C>T p.P97= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1020958547; called by muse, mutect2, varscan2
- SOCS4 | c.771G>A p.Q257= | Silent (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
- SYMPK | c.234C>T p.I78= | Silent (SNP) | VAF 60/313 reads (19%) | catalogued as rs188023108, COSV55615073; called by muse, mutect2, varscan2
- WDR1 | c.1377G>A p.T459= (on ENST00000382452; = p.T319= on NM_005112.5) | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs754699425, COSV101221170; called by muse, mutect2, varscan2
- ZNF143 | c.1641G>A p.T547= | Silent (SNP) | VAF 54/245 reads (22%) | catalogued as rs572827042, COSV55182215; called by muse, mutect2, varscan2
- ZNF627 | c.1137A>T p.R379= | Silent (SNP) | VAF 32/194 reads (16%) | called by muse, mutect2, varscan2
- ALK | c.3516-162_3516-161insAAGAT | Intron (INS) | VAF 27/109 reads (25%) | called by mutect2, varscan2*
- ARL13B | c.*786T>G | 3'UTR (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- CTDSP1 | c.68-669C>A | Intron (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- CTSA | c.195-42G>T | Intron (SNP) | VAF 71/317 reads (22%) | called by muse, mutect2, varscan2
- FAM24B | chr10:122883863 G>A | 5'Flank (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- MAP2K3 | c.49+3102G>A | Intron (SNP) | VAF 48/302 reads (16%) | catalogued as rs1403589133; called by muse, mutect2, varscan2
- MYH9 | c.5592+16G>T | Intron (SNP) | VAF 81/387 reads (21%) | called by muse, mutect2, varscan2
- RAB40C | chr16:630394 C>T | 3'Flank (SNP) | VAF 14/62 reads (23%) | catalogued as rs1423129951; called by muse, mutect2, varscan2
- S1PR3 | c.-148+192C>T | Intron (SNP) | VAF 138/625 reads (22%) | catalogued as rs774548704; called by muse, mutect2, varscan2
- SAYSD1 | c.208-3542T>G | Intron (SNP) | VAF 28/171 reads (16%) | called by muse, mutect2, varscan2
- SMIM8 | n.522G>A | RNA (SNP) | VAF 14/72 reads (19%) | catalogued as rs1206953256; called by mutect2, varscan2
- TPR | c.-103G>C | 5'UTR (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- ZNF658B | n.865A>T | RNA (SNP) | VAF 117/513 reads (23%) | called by muse, mutect2, varscan2
